Gene-level copy-number profile of tumor specimen C3L-04795-02 from CPTAC case C3L-04795, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 37.0 years (13,503 days).
Specimen C3L-04795-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 721a1dc2-9350-4fae-a86f-064b22016197.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04795-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/7ae81bd1-f3fd-4439-a857-7ce86a9e0b5f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 33; copy number 2: 9,375; copy number 3: 2,698; copy number 4: 45,698; copy number 5: 261; copy number 6: 696; copy number 32: 27; copy number 38: 2; copy number 57: 2; copy number 58: 11; copy number 60: 9; copy number 66: 1; copy number 70: 3; copy number 71: 11; copy number 74: 2; copy number 75: 41; copy number 85: 3; copy number 89: 2; copy number 94: 1; copy number 96: 4; copy number 115: 12; copy number 123: 5; copy number 134: 5.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:26,015,669–26,016,369, 1 gene: RPEP2.
- chr4:181,064,089–181,237,564, 2 genes: LINC00290, AC019235.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 141 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,690,782–17,518,439, 29 genes, copy number 85–134: LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866, RN7SKP168, ZFYVE9P2, PSMC1P10, RAD51AP2.
- chr4:1,211,445–2,242,276, 27 genes, copy number 32 (within-gene range 6–32): CTBP1, CTBP1-DT, MAEA, UVSSA, AC078852.2, AC078852.1, NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L, POLN, HAUS3, AL136360.1, AL136360.2.
- chr12:19,129,752–19,376,400, 1 gene, copy number 70 (within-gene range 4–70): PLEKHA5.
- chr12:19,176,288–19,303,775, 2 genes, copy number 70: RN7SL459P, RN7SL67P.
- chr12:30,861,921–30,862,179, 1 gene, copy number 66: PPIAP44.
- chr12:57,591,174–57,896,846, 30 genes, copy number 75: PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3.
- chr12:57,930,115–57,936,345, 1 gene, copy number 75: GIHCG.
- chr12:80,707,634–81,261,210, 10 genes, copy number 75 (within-gene range 4–75): MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699.
- chr12:103,503,381–103,504,936, 1 gene, copy number 94: AC084364.1.
- chr12:110,831,779–110,845,963, 2 genes, copy number 74: AC002375.1, RPL29P25.
- chr12:112,570,380–112,898,881, 2 genes, copy number 57: RPH3A, MIR1302-1.
- chr12:121,308,245–121,672,631, 9 genes, copy number 60: ANAPC5, AC048337.1, RNF34, KDM2B, MIR7107, KDM2B-DT, RNU6-1004P, ORAI1, MORN3.
- chr12:123,081,384–123,092,821, 2 genes, copy number 89: PITPNM2-AS1, AC026362.2.
- chr12:130,024,493–130,266,725, 11 genes, copy number 58: AC055717.2, LINC02418, AC135388.1, LINC02419, AC026336.4, AC026336.3, FZD10-AS1, AC026336.5, FZD10, AC026336.1, AC026336.2.
- chr12:131,165,011–131,455,436, 11 genes, copy number 71: LINC01257, AC126564.1, RPS6P20, AC092850.1, LINC02415, RNA5SP376, LINC02370, AC140118.2, AC140118.1, AC073578.4, AC073578.2.
- chr12:132,457,160–132,462,856, 2 genes, copy number 38: AC079031.1, AC079031.2.

Autosomal genes at a single copy (total copy number 1): 31. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
